Somatic mutation profile of tumor specimen ALCH-AEDW-TTP1-A (aliquot ALCH-AEDW-TTP1-A-1-0-D-A605-36) from ALCHEMIST case ALCH-AEDW, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 53.3 years (19,461 days).
Specimen ALCH-AEDW-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ba45fd74-8117-410a-b73a-1e868362706c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEDW-NB1-A (Blood Derived Normal), aliquot ALCH-AEDW-NB1-A-1-0-D-A605-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ab87f86a-3074-46dd-9a68-4b3087bf1896

The open-access MAF lists 1,175 somatic variants for this specimen: 792 protein-altering or splice-affecting, 211 silent, 172 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 680, Silent 211, Intron 83, Nonsense Mutation 45, 3'UTR 26, 5'UTR 24, Splice Site 24, Frame Shift Del 23, RNA 22, 5'Flank 12, Frame Shift Ins 11, Splice Region 7.

Variants (750 of 1,175; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL4A4 | c.3151-2A>G p.X1051_splice | Splice Site (SNP) | VAF 234/934 reads (25%) | catalogued as rs1369097739; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.378C>G p.Y126* | Nonsense Mutation (SNP) | VAF 105/337 reads (31%) | hotspot (GDC flag); catalogued as rs1567554500, CM1414507, COSV52662583, COSV52757878, COSV52964885, COSV53125652; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB11 | c.235G>A p.V79M | Missense Mutation (SNP) | VAF 103/384 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs371965391; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTR3B | c.684G>C p.K228N | Missense Mutation (SNP) | VAF 67/177 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV55449081; called by muse, mutect2, varscan2
- ACVRL1 | c.557G>T p.S186I | Missense Mutation (SNP) | VAF 317/675 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1288729113; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADCY2 | c.1326G>C p.E442D | Missense Mutation (SNP) | VAF 47/408 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57901571; called by muse, mutect2, varscan2
- ADGRL3 | c.1887G>T p.K629N (on ENST00000506720 / NM_001322402.2; = p.K561N on NM_015236.6) | Missense Mutation (SNP) | VAF 76/313 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.772); catalogued as COSV72230417, COSV72230467; called by muse, mutect2, varscan2
- ADGRV1 | c.3994G>T p.G1332* | Nonsense Mutation (SNP) | VAF 150/426 reads (35%) | catalogued as COSV101315511, COSV67983679; called by muse, mutect2, varscan2
- AFM | c.1402T>G p.F468V | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as COSV56919203; called by muse, varscan2
- AHNAK | c.354C>A p.S118R | Missense Mutation (SNP) | VAF 33/265 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs749434396; called by muse, mutect2, varscan2
- ALPK2 | c.3562G>T p.G1188C | Missense Mutation (SNP) | VAF 36/163 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as COSV100864386; called by muse, mutect2, varscan2
- ALX4 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 27/158 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.975); catalogued as COSV100240976, COSV61325140; called by muse, mutect2, varscan2
- AMER1 | c.386G>T p.S129I | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.859); catalogued as COSV100365722; called by muse, mutect2, varscan2
- ANKRD30B | c.3476C>T p.T1159I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs1412863393; called by muse, varscan2
- ANKZF1 | c.672-2A>G p.X224_splice | Splice Site (SNP) | VAF 170/637 reads (27%) | catalogued as rs1336245832; called by muse, mutect2, varscan2
- ANTXR2 | c.697+1del p.X233_splice | Splice Site (DEL) | VAF 99/406 reads (24%) | catalogued as rs774904646, CS033827; called by mutect2, pindel, varscan2
- APOB | c.12445del p.Q4149Rfs*8 | Frame Shift Del (DEL) | VAF 9/67 reads (13%) | catalogued as COSV99266993; called by mutect2, varscan2
- ARHGAP28 | c.506G>T p.R169M (on ENST00000383472 / NM_001366230.1; = p.R10M on NM_001010000.3) | Missense Mutation (SNP) | VAF 82/438 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as COSV51640459, COSV99151330; called by muse, mutect2, varscan2
- ARHGAP32 | c.5129G>T p.R1710L (on ENST00000310343 / NM_001378025.1; = p.R1361L on NM_014715.4) | Missense Mutation (SNP) | VAF 47/343 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.163); catalogued as rs745850730, COSV100088774; called by muse, mutect2, varscan2
- ARID5A | c.1666C>T p.P556S | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs199541629; called by muse, mutect2, varscan2
- ARSF | c.454del p.H152Tfs*32 | Frame Shift Del (DEL) | VAF 50/134 reads (37%) | catalogued as COSV63840392; called by mutect2, varscan2
- BCOR | c.193G>A p.D65N | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.995); catalogued as COSV60713441; called by muse, mutect2, varscan2
- BHLHE22 | c.961C>A p.L321M | Missense Mutation (SNP) | VAF 95/636 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.73); catalogued as rs1308249425, COSV100417882; called by muse, mutect2, varscan2
- BMP15 | c.610C>T p.R204* | Nonsense Mutation (SNP) | VAF 124/247 reads (50%) | catalogued as rs991314787, COSV53140530; called by muse, mutect2, varscan2
- BNC2 | c.3062G>T p.G1021V | Missense Mutation (SNP) | VAF 186/593 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.521); catalogued as rs891839945; called by muse, mutect2, varscan2
- BSN | c.9860G>T p.G3287V | Missense Mutation (SNP) | VAF 58/303 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.814); catalogued as COSV56519623; called by muse, mutect2, varscan2
- C16orf78 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 220/585 reads (38%) | catalogued as COSV54558486; called by muse, mutect2, varscan2
- C3orf22 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as rs142130143; called by muse, mutect2, varscan2
- CACNA2D4 | c.1613G>A p.R538K | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.096); catalogued as COSV54959574; called by muse, mutect2, varscan2
- CADPS | c.2254A>T p.S752C | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV51872124; called by muse, mutect2, varscan2
- CARTPT | c.69G>T p.L23F | Missense Mutation (SNP) | VAF 168/485 reads (35%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.446); catalogued as COSV99703898; called by muse, mutect2, varscan2
- CASP2 | c.66G>T p.R22S | Missense Mutation (SNP) | VAF 47/369 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.055); catalogued as rs769894317; called by muse, mutect2, varscan2
- CCDC80 | c.1318G>T p.E440* | Nonsense Mutation (SNP) | VAF 129/637 reads (20%) | catalogued as COSV99244865; called by muse, mutect2, varscan2
- CCDC88C | c.5197G>A p.V1733I | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.005); catalogued as rs369187490; called by muse, mutect2, varscan2
- CD1B | c.486C>A p.F162L | Missense Mutation (SNP) | VAF 77/483 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV63805065; called by muse, mutect2, varscan2
- CDC20B | c.733G>T p.V245F | Missense Mutation (SNP) | VAF 42/138 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs1254464262, COSV57053062; called by muse, varscan2
- CDH10 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 79/294 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050417, COSV52571595; called by muse, mutect2, varscan2
- CDH11 | c.1391A>G p.H464R | Missense Mutation (SNP) | VAF 84/189 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs1304893278; called by muse, mutect2, varscan2
- CDH11 | c.740G>T p.G247V | Missense Mutation (SNP) | VAF 100/326 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99217735; called by muse, mutect2, varscan2
- CDH12 | c.1069C>T p.H357Y | Missense Mutation (SNP) | VAF 102/729 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV66405141; called by muse, mutect2, varscan2
- CLCNKA | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 71/404 reads (18%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.796); catalogued as COSV58892177; called by muse, mutect2, varscan2
- CNRIP1 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 39/305 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as rs768071705; called by muse, mutect2, varscan2
- CNTN5 | c.533C>T p.T178I | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV54307565, COSV99671966; called by muse, mutect2, varscan2
- CNTN5 | c.1051C>A p.Q351K | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.994); catalogued as COSV99680543; called by muse, mutect2, varscan2
- CNTNAP2 | c.1748C>T p.T583I | Missense Mutation (SNP) | VAF 46/476 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs199578386; called by muse, mutect2
- CNTNAP5 | c.23C>A p.T8N | Missense Mutation (SNP) | VAF 87/425 reads (20%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as rs1014303686, COSV70489152; called by muse, mutect2, varscan2
- COL12A1 | c.4561-1G>A p.X1521_splice | Splice Site (SNP) | VAF 58/176 reads (33%) | catalogued as COSV59391537; called by muse, mutect2, varscan2
- COL22A1 | c.3185C>A p.P1062Q | Missense Mutation (SNP) | VAF 135/407 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.026); catalogued as COSV57363929; called by muse, mutect2, varscan2
- COL4A3 | c.53T>C p.L18P | Missense Mutation (SNP) | VAF 35/354 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs767333630; called by muse, mutect2
- COL5A1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 137/503 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.105); catalogued as rs777789161, COSV65676491; called by muse, mutect2, varscan2
- COL5A3 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.251); catalogued as rs780192950, COSV53419871; called by muse, mutect2, varscan2
- CSMD3 | c.5561C>A p.S1854* (on ENST00000297405 / NM_001363185.1; = p.S1750* on NM_052900.3) | Nonsense Mutation (SNP) | VAF 60/561 reads (11%) | catalogued as COSV52169723, COSV99833841; called by muse, mutect2, varscan2
- CSMD3 | c.1342G>C p.V448L | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as COSV52130346; called by muse, mutect2, varscan2
- DAB1 | c.714A>T p.Q238H | Missense Mutation (SNP) | VAF 37/305 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100140444; called by muse, mutect2, varscan2
- DCX | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 140/327 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as rs1230386660, COSV57572451; called by muse, mutect2, varscan2
- DENND4A | c.2286G>T p.R762S | Missense Mutation (SNP) | VAF 108/979 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as rs185666711; called by muse, mutect2
- DNAI1 | c.228C>A p.H76Q | Missense Mutation (SNP) | VAF 155/1248 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.296); catalogued as COSV54283876; called by muse, mutect2, varscan2
- DNMT3B | c.809C>T p.S270F | Missense Mutation (SNP) | VAF 26/225 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52422424; called by muse, mutect2, varscan2
- DPPA2 | c.230G>A p.R77K | Missense Mutation (SNP) | VAF 64/672 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs921473110; called by muse, mutect2
- EHHADH | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 61/212 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as rs776874092, COSV51628497; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EIF4E1B | c.280G>T p.V94L | Missense Mutation (SNP) | VAF 77/249 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as COSV53780775; called by muse, mutect2, varscan2
- ELMO1 | c.1906-4G>A | Splice Region (SNP) | VAF 173/422 reads (41%) | catalogued as rs371888413; called by muse, mutect2, varscan2
- ENAM | c.1402A>T p.K468* | Nonsense Mutation (SNP) | VAF 104/394 reads (26%) | catalogued as COSV68536088; called by muse, mutect2, varscan2
- EPHA4 | c.721G>T p.D241Y | Missense Mutation (SNP) | VAF 83/628 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV56027732; called by muse, mutect2, varscan2
- EXOSC10 | c.775C>G p.Q259E | Missense Mutation (SNP) | VAF 48/276 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.011); catalogued as COSV58665612; called by muse, mutect2, varscan2
- F2RL2 | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 106/256 reads (41%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as rs757538626; called by muse, mutect2, varscan2
- FAM160A1 | c.2316G>T p.Q772H | Missense Mutation (SNP) | VAF 100/910 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.135); catalogued as COSV104437095; called by muse, mutect2, varscan2
- FAM47A | c.820del p.E274Kfs*66 | Frame Shift Del (DEL) | VAF 36/174 reads (21%) | catalogued as COSV100650047; called by mutect2, pindel, varscan2
- FAT3 | c.12460G>C p.E4154Q | Missense Mutation (SNP) | VAF 45/279 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99972420; called by muse, mutect2, varscan2
- FGF14 | c.740C>A p.T247K | Missense Mutation (SNP) | VAF 102/554 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); catalogued as COSV101085197; called by muse, mutect2, varscan2
- FIG4 | c.1769C>T p.S590F | Missense Mutation (SNP) | VAF 101/373 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs773166475, COSV57787294; called by muse, mutect2, varscan2
- FLG | c.941C>A p.S314Y | Missense Mutation (SNP) | VAF 150/761 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV64242420; called by muse, mutect2, varscan2
- FLNB | c.4454C>T p.P1485L | Missense Mutation (SNP) | VAF 137/810 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV55888894; called by muse, mutect2, varscan2
- FLNC | c.1649C>A p.T550K | Missense Mutation (SNP) | VAF 711/1052 reads (68%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.827); catalogued as rs779802575; called by muse, mutect2, varscan2
- FLT3 | c.259G>A p.A87T | Missense Mutation (SNP) | VAF 63/408 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.226); catalogued as rs753172215, COSV99058826; called by muse, mutect2, varscan2
- GATAD2B | c.1580G>T p.R527L | Missense Mutation (SNP) | VAF 54/232 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV64084564; called by muse, mutect2, varscan2
- GGA3 | c.253G>T p.G85W | Missense Mutation (SNP) | VAF 64/518 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55456626; called by muse, mutect2, varscan2
- GJD4 | c.349C>A p.P117T | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as rs370405105; called by muse, mutect2, varscan2
- GLI2 | c.1819G>A p.G607S (on ENST00000361492 / NM_001374353.1; = p.G624S on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.64); PolyPhen benign (0.015); catalogued as rs754383625; called by muse, mutect2, varscan2
- GLYR1 | c.1005G>T p.K335N | Missense Mutation (SNP) | VAF 236/404 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.592); catalogued as rs755116976; called by muse, mutect2, varscan2
- GPR52 | c.202G>T p.A68S | Missense Mutation (SNP) | VAF 52/373 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); catalogued as COSV52330129; called by muse, mutect2, varscan2
- GRIK2 | c.1426T>C p.F476L | Missense Mutation (SNP) | VAF 137/388 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100029824; called by muse, mutect2, varscan2
- GRK6 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 66/238 reads (28%) | catalogued as COSV62682720; called by muse, mutect2, varscan2
- GRM8 | c.1372C>A p.P458T | Missense Mutation (SNP) | VAF 162/496 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.099); catalogued as COSV58883865; called by muse, mutect2, varscan2
- GSE1 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 58/90 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1445418376; called by muse, mutect2, varscan2
- GTSF1 | c.145G>T p.A49S | Missense Mutation (SNP) | VAF 197/434 reads (45%) | SIFT deleterious (0.02); PolyPhen benign (0.345); catalogued as COSV59938367; called by muse, mutect2, varscan2
- HDAC9 | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 43/528 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.282); catalogued as rs1435233030, COSV67777245; called by muse, mutect2
- HEATR5A | c.3566G>T p.C1189F | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.024); catalogued as COSV101120290; called by muse, varscan2
- HOXA3 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 70/150 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.053); catalogued as rs1205537984, COSV57828997; called by muse, varscan2
- HOXD12 | c.334C>A p.R112S | Missense Mutation (SNP) | VAF 75/371 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.631); catalogued as COSV66832326; called by muse, mutect2, varscan2
- IFI44 | c.1249G>T p.A417S | Missense Mutation (SNP) | VAF 75/591 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.569); catalogued as rs1253463609; called by muse, mutect2, varscan2
- IHH | c.853G>T p.E285* | Nonsense Mutation (SNP) | VAF 76/280 reads (27%) | catalogued as COSV99838829; called by muse, mutect2, varscan2
- IL1R2 | c.290C>T p.P97L | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60205522; called by muse, mutect2, varscan2
- IMPG1 | c.1090G>A p.E364K | Missense Mutation (SNP) | VAF 164/469 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.027); catalogued as rs867436235, COSV64059481; called by muse, mutect2, varscan2
- INSRR | c.3527G>T p.W1176L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs576165880, COSV100947355; called by muse, mutect2, varscan2
- INSYN1 | c.42C>A p.D14E | Missense Mutation (SNP) | VAF 54/312 reads (17%) | SIFT tolerated (0.88); PolyPhen probably damaging (0.997); catalogued as COSV101138736; called by muse, mutect2, varscan2
- ITGA8 | c.2228G>A p.R743Q | Missense Mutation (SNP) | VAF 42/399 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs953130704; called by muse, mutect2, varscan2
- ITGAV | c.423G>T p.L141F | Missense Mutation (SNP) | VAF 94/343 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV99654189; called by muse, varscan2
- IZUMO3 | c.279A>T p.K93N | Missense Mutation (SNP) | VAF 62/243 reads (26%) | SIFT tolerated (0.25); catalogued as rs1379361147; called by muse, varscan2
- JARID2 | c.1283G>T p.R428L | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.058); catalogued as COSV100522176; called by muse, mutect2, varscan2
- KDM4C | c.372del p.W124* | Frame Shift Del (DEL) | VAF 42/178 reads (24%) | catalogued as COSV101185161; called by mutect2, pindel, varscan2
- KIAA0408 | c.2076G>C p.L692F | Missense Mutation (SNP) | VAF 67/339 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100847509; called by muse, mutect2, varscan2
- KIDINS220 | c.3734G>A p.R1245H | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs61742970, COSV56752027; called by muse, mutect2, varscan2
- KLHL11 | c.2099G>T p.R700L | Missense Mutation (SNP) | VAF 40/114 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV59862765; called by muse, mutect2, varscan2
- KPRP | c.1004C>A p.P335H | Missense Mutation (SNP) | VAF 31/182 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100908670; called by muse, mutect2, varscan2
- LAMA2 | c.4229C>G p.P1410R | Missense Mutation (SNP) | VAF 308/955 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.534); catalogued as rs769665275, COSV70342597; called by muse, mutect2, varscan2
- LHFPL3 | c.443G>T p.G148V | Missense Mutation (SNP) | VAF 214/422 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV67821335; called by muse, mutect2, varscan2
- LIN7A | c.224C>A p.T75K | Missense Mutation (SNP) | VAF 148/387 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.736); catalogued as COSV54017859; called by mutect2, varscan2
- MAN2C1 | c.419G>T p.R140L | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.089); catalogued as rs201676861, COSV51226599; called by muse, mutect2, varscan2
- MDM1 | c.1720-1G>T p.X574_splice | Splice Site (SNP) | VAF 44/76 reads (58%) | catalogued as rs776852538; called by muse, mutect2, varscan2
- MED12L | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 161/582 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.086); catalogued as COSV56402659; called by muse, mutect2, varscan2
- MED16 | c.1189C>A p.L397I | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1007902715; called by muse, mutect2, varscan2
- METTL16 | c.1327G>T p.A443S | Missense Mutation (SNP) | VAF 73/174 reads (42%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as rs200997068; called by muse, mutect2, varscan2
- MFSD9 | c.61G>T p.E21* | Nonsense Mutation (SNP) | VAF 60/326 reads (18%) | catalogued as COSV99302259; called by muse, mutect2, varscan2
- MLPH | c.574G>T p.V192F | Missense Mutation (SNP) | VAF 131/765 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.019); catalogued as COSV52820067; called by muse, mutect2, varscan2
- MORC1 | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 148/644 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV51733747; called by muse, mutect2, varscan2
- MROH2A | c.648G>T p.K216N | Missense Mutation (SNP) | VAF 41/309 reads (13%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.968); catalogued as rs757600100; called by muse, mutect2, varscan2
- MROH2B | c.595C>A p.P199T | Missense Mutation (SNP) | VAF 25/185 reads (14%) | SIFT tolerated (0.77); PolyPhen benign (0.01); catalogued as COSV101270782; called by muse, mutect2, varscan2
- MRS2 | c.1164C>G p.I388M | Missense Mutation (SNP) | VAF 48/348 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.88); catalogued as rs141780681; called by muse, mutect2, varscan2
- MUC16 | c.19142C>G p.S6381* | Nonsense Mutation (SNP) | VAF 36/289 reads (12%) | catalogued as COSV67475666; called by muse, mutect2, varscan2
- MUC17 | c.2519C>A p.S840Y | Missense Mutation (SNP) | VAF 31/248 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV60280825; called by muse, mutect2, varscan2
- MYH13 | c.2390G>T p.R797M | Missense Mutation (SNP) | VAF 141/386 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99352194, COSV99354806; called by muse, mutect2, varscan2
- MYH2 | c.2362G>T p.A788S | Missense Mutation (SNP) | VAF 300/948 reads (32%) | SIFT tolerated (0.64); PolyPhen benign (0.013); catalogued as COSV99821104; called by muse, mutect2, varscan2
- MYH6 | c.4768C>A p.R1590S | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs544624250; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH6 | c.3785G>T p.R1262L | Missense Mutation (SNP) | VAF 194/623 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as COSV62452215; called by muse, mutect2, varscan2
- MYL2 | c.421G>A p.A141T | Missense Mutation (SNP) | VAF 211/440 reads (48%) | SIFT tolerated (0.55); PolyPhen benign (0.355); catalogued as rs727504559, COSV57407889; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAALAD2 | c.2198C>G p.A733G | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.244); catalogued as rs778666259; called by muse, mutect2, varscan2
- NEURL3 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.053); catalogued as rs549194101; called by mutect2, varscan2
- NIPBL | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 31/184 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); catalogued as rs1474532522; called by muse, mutect2, varscan2
- NLGN1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 119/456 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV64345137; called by muse, mutect2, varscan2
- NLRP7 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60179995; called by muse, mutect2, varscan2
- NOX4 | c.312C>A p.F104L | Missense Mutation (SNP) | VAF 24/212 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV54459589; called by muse, varscan2
- NPBWR2 | c.553G>T p.A185S | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as rs538624857; called by muse, mutect2, varscan2
- NPC1L1 | c.1085C>A p.P362Q | Missense Mutation (SNP) | VAF 91/265 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.157); catalogued as COSV56924771; called by muse, mutect2, varscan2
- NPR1 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 26/169 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.067); catalogued as rs750918391, COSV64142325; called by muse, mutect2, varscan2
- NR0B1 | c.826C>G p.Q276E | Missense Mutation (SNP) | VAF 66/210 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as CM109526; called by muse, varscan2
- NRAP | c.2632G>T p.V878F (on ENST00000359988 / NM_001322945.2; = p.V843F on NM_006175.4) | Missense Mutation (SNP) | VAF 99/801 reads (12%) | SIFT tolerated (0.76); PolyPhen benign (0.082); catalogued as rs759489224; called by muse, mutect2, varscan2
- NRXN1 | c.2380G>T p.G794C | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV58441151; called by muse, mutect2, varscan2
- NWD2 | c.4604A>G p.N1535S | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); catalogued as rs577535323; called by muse, mutect2, varscan2
- OGDHL | c.922G>A p.V308M | Missense Mutation (SNP) | VAF 36/295 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1040441881, COSV65101329; called by muse, varscan2
- OLFM3 | c.1262C>A p.S421Y (on ENST00000338858 / NM_001288821.1; = p.S401Y on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.995); catalogued as COSV100129014, COSV58799236; called by muse, mutect2, varscan2
- OLFML2B | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.358); catalogued as rs756559531, COSV54197728; called by muse, mutect2, varscan2
- OPA1 | c.2323G>T p.D775Y (on ENST00000361510 / NM_130837.3; = p.D720Y on NM_015560.3) | Missense Mutation (SNP) | VAF 127/570 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV100655501; called by muse, mutect2, varscan2
- OR13C5 | c.121G>A p.G41R | Missense Mutation (SNP) | VAF 28/421 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769956576; called by muse, mutect2, varscan2
- OR13H1 | c.186C>A p.F62L | Missense Mutation (SNP) | VAF 137/266 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58547159; called by muse, mutect2, varscan2
- OR14C36 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1489983438; called by muse, mutect2, varscan2
- OR1L1 | c.743C>T p.T248I (on ENST00000373686; = p.T198I on NM_001005236.3) | Missense Mutation (SNP) | VAF 38/277 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.209); catalogued as rs1393848408; called by muse, mutect2, varscan2
- OR2L13 | c.229G>T p.V77F | Missense Mutation (SNP) | VAF 50/301 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63547540, COSV63561899; called by muse, mutect2, varscan2
- OR2W1 | c.371C>A p.T124K | Missense Mutation (SNP) | VAF 26/264 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV101013903; called by muse, mutect2
- OR4C16 | c.752C>A p.P251H | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs555112423, COSV58943406; called by muse, mutect2, varscan2
- OR52B4 | c.803G>A p.R268H | Missense Mutation (SNP) | VAF 48/358 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773531327, COSV68768793; called by muse, mutect2, varscan2
- OR52J3 | c.483G>C p.M161I | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as COSV100984955, COSV66747705; called by muse, mutect2, varscan2
- OR5AK2 | c.514A>G p.N172D | Missense Mutation (SNP) | VAF 43/288 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1272082302; called by muse, mutect2, varscan2
- OR5D18 | c.125G>T p.G42V | Missense Mutation (SNP) | VAF 25/194 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100450565; called by muse, mutect2
- OR5W2 | c.512C>A p.S171Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100747631; called by muse, mutect2
- OR9G1 | c.525C>A p.D175E | Missense Mutation (SNP) | VAF 48/501 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100380500; called by muse, mutect2
- OTULINL | c.1008G>T p.R336S | Missense Mutation (SNP) | VAF 75/482 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as COSV99947078; called by muse, mutect2, varscan2
- OVCH2 | c.920C>A p.S307Y | Missense Mutation (SNP) | VAF 65/406 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.047); catalogued as COSV71952809; called by muse, mutect2, varscan2
- PCDH10 | c.1924C>A p.R642S | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52095992, COSV52096272; called by muse, mutect2, varscan2
- PCDH17 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 61/380 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64972091; called by muse, mutect2, varscan2
- PCDHAC2 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 108/324 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53863442; called by muse, mutect2, varscan2
- PCLO | c.4410G>T p.E1470D | Missense Mutation (SNP) | VAF 43/347 reads (12%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as rs758585139, COSV61636337; called by muse, mutect2, varscan2
- PDE7B | c.1346G>T p.S449I | Missense Mutation (SNP) | VAF 61/195 reads (31%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV100367714; called by muse, mutect2, varscan2
- PIWIL1 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 200/501 reads (40%) | SIFT tolerated (0.91); PolyPhen probably damaging (0.91); catalogued as rs150787742; called by muse, mutect2, varscan2
- PKHD1L1 | c.6874G>T p.G2292C | Missense Mutation (SNP) | VAF 29/168 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101006467; called by muse, mutect2
- PLEC | c.12634G>A p.E4212K (on ENST00000322810 / NM_201380.4; = p.E4102K on NM_000445.5) | Missense Mutation (SNP) | VAF 186/439 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV59605904; called by muse, mutect2, varscan2
- PLEC | c.8863C>T p.P2955S (on ENST00000322810 / NM_201380.4; = p.P2845S on NM_000445.5) | Missense Mutation (SNP) | VAF 52/166 reads (31%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV59600041; called by muse, varscan2
- PLK1 | c.613G>T p.G205W | Missense Mutation (SNP) | VAF 51/279 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779641699; called by muse, mutect2, varscan2
- POP1 | c.2006G>T p.G669V | Missense Mutation (SNP) | VAF 234/756 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62892202; called by muse, mutect2, varscan2
- PPFIA2 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 48/323 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766828318, COSV61049620; called by muse, mutect2, varscan2
- PRAME | c.18G>T p.L6F | Missense Mutation (SNP) | VAF 52/391 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.178); catalogued as COSV67161469; called by muse, mutect2, varscan2
- PRDM5 | c.533G>T p.S178I | Missense Mutation (SNP) | VAF 170/523 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.628); catalogued as rs954624177, COSV53362233; called by muse, mutect2, varscan2
- PRKD1 | c.682G>T p.D228Y | Missense Mutation (SNP) | VAF 123/333 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV59566973; called by muse, mutect2, varscan2
- PRPH2 | c.709G>C p.D237H | Missense Mutation (SNP) | VAF 150/856 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs761932874; called by muse, mutect2, varscan2
- PRSS1 | c.454G>T p.A152S | Missense Mutation (SNP) | VAF 81/595 reads (14%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV100298009, COSV61195597; called by muse, mutect2, varscan2
- PRSS16 | c.634del p.V212Cfs*18 | Frame Shift Del (DEL) | VAF 55/440 reads (13%) | catalogued as rs1561773398; called by mutect2, pindel, varscan2
- PSG7 | c.394G>T p.G132* | Nonsense Mutation (SNP) | VAF 105/268 reads (39%) | catalogued as COSV101343202; called by muse, mutect2, varscan2
- PSME4 | c.5285G>T p.G1762V | Missense Mutation (SNP) | VAF 60/255 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101122430; called by muse, mutect2, varscan2
- PTGER3 | c.1174C>A p.R392S | Missense Mutation (SNP) | VAF 65/305 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV63037065; called by muse, mutect2, varscan2
- PXDNL | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 13/155 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV62479845; called by muse, mutect2
- RAB11FIP5 | c.1361G>T p.R454L | Missense Mutation (SNP) | VAF 128/520 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.598); catalogued as COSV50253717; called by muse, mutect2, varscan2
- RADX | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 42/222 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as rs147676341; called by muse, mutect2, varscan2
- RIMBP3 | c.2660G>A p.G887E | Missense Mutation (SNP) | VAF 97/1388 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371846019; called by muse, mutect2
- RPL10L | c.587G>T p.G196V | Missense Mutation (SNP) | VAF 77/229 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.35); catalogued as COSV100022794, COSV53559550; called by muse, mutect2, varscan2
- RPS20 | c.49A>G p.I17V | Missense Mutation (SNP) | VAF 116/887 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs1282900749; called by muse, mutect2, varscan2
- RTL3 | c.1425G>T p.Q475H | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.276); catalogued as COSV58185044; called by muse, varscan2
- RXFP2 | c.947C>A p.T316K | Missense Mutation (SNP) | VAF 61/361 reads (17%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV53634652; called by muse, mutect2, varscan2
- RXFP3 | c.1244T>A p.M415K | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs958531236; called by muse, mutect2, varscan2
- SALL1 | c.1799C>T p.S600L | Missense Mutation (SNP) | VAF 54/137 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1478555114; called by muse, mutect2, varscan2
- SALL4 | c.1951G>T p.G651C | Missense Mutation (SNP) | VAF 235/762 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53855331, COSV53856874; called by muse, mutect2, varscan2
- SAMD9L | c.102del p.Q35Kfs*8 | Frame Shift Del (DEL) | VAF 143/414 reads (35%) | catalogued as COSV59084579; called by mutect2, pindel, varscan2
- SCG3 | c.540+1G>T p.X180_splice | Splice Site (SNP) | VAF 19/72 reads (26%) | catalogued as rs903604916, COSV55020570; called by muse, mutect2
- SCGN | c.364A>T p.S122C | Missense Mutation (SNP) | VAF 68/400 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58547773; called by muse, mutect2, varscan2
- SCN3A | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 47/400 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV99325498; called by muse, mutect2, varscan2
- SCN4A | c.5132C>T p.S1711F | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.947); catalogued as rs899418878, COSV71125804; called by muse, mutect2, varscan2
- SEL1L3 | c.2164C>A p.L722M | Missense Mutation (SNP) | VAF 64/397 reads (16%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.951); catalogued as COSV53539786; called by muse, mutect2, varscan2
- SENP3 | c.85C>T p.R29W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.056); catalogued as COSV53435689; called by muse, mutect2, varscan2
- SGSM1 | c.1876G>A p.V626M | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs376508684; called by muse, mutect2, varscan2
- SH3BP4 | c.2573G>A p.R858Q | Missense Mutation (SNP) | VAF 24/290 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as rs754479794, COSV100749020; called by muse, mutect2
- SHCBP1L | c.1588G>T p.G530C | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1320710413; called by muse, mutect2, varscan2
- SIGLEC10 | c.1837C>G p.Q613E | Missense Mutation (SNP) | VAF 27/155 reads (17%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV59487609; called by muse, mutect2, varscan2
- SIGLEC15 | c.697G>A p.G233S | Missense Mutation (SNP) | VAF 58/281 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs765318389; called by muse, mutect2, varscan2
- SIX3 | c.778C>G p.R260G | Missense Mutation (SNP) | VAF 31/252 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53228596; called by muse, mutect2, varscan2
- SLC12A9 | c.689C>G p.S230C | Missense Mutation (SNP) | VAF 52/274 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.518); catalogued as COSV51935807; called by muse, mutect2, varscan2
- SLC26A7 | c.1957C>T p.H653Y | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.491); catalogued as rs775350667; called by muse, mutect2
- SLC2A2 | c.262G>T p.A88S | Missense Mutation (SNP) | VAF 183/794 reads (23%) | SIFT tolerated (0.87); PolyPhen benign (0.015); catalogued as rs763255363; called by muse, mutect2, varscan2
- SLC32A1 | c.1246G>A p.A416T | Missense Mutation (SNP) | VAF 39/119 reads (33%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs142909531; called by muse, mutect2, varscan2
- SLC39A1 | c.655G>C p.G219R | Missense Mutation (SNP) | VAF 30/209 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.82); catalogued as COSV57845380; called by muse, mutect2, varscan2
- SLC5A12 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 108/782 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54822049; called by muse, mutect2, varscan2
- SLC5A5 | c.931G>A p.D311N | Missense Mutation (SNP) | VAF 99/654 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs138250437; called by muse, mutect2, varscan2
- SLC9C2 | c.1106G>A p.W369* | Nonsense Mutation (SNP) | VAF 56/364 reads (15%) | catalogued as rs986965280; called by muse, mutect2, varscan2
- SLCO1B3 | c.680G>T p.G227V | Missense Mutation (SNP) | VAF 116/280 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); catalogued as COSV53940869; called by muse, mutect2, varscan2
- SLITRK1 | c.487G>T p.D163Y | Missense Mutation (SNP) | VAF 171/930 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV65675257; called by muse, mutect2, varscan2
- SPAG6 | c.1249C>T p.L417F | Missense Mutation (SNP) | VAF 30/278 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57619260; called by muse, mutect2, varscan2
- STAU1 | c.824C>T p.P275L (on ENST00000371856 / NM_001319135.1; = p.P194L on NM_004602.3) | Missense Mutation (SNP) | VAF 85/659 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV61460597; called by muse, mutect2, varscan2
- SUGP1 | c.1554G>T p.M518I | Missense Mutation (SNP) | VAF 133/586 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV99894704; called by muse, mutect2, varscan2
- SUN5 | c.77G>T p.R26M | Missense Mutation (SNP) | VAF 46/157 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); catalogued as rs867518817; called by muse, mutect2, varscan2
- SVEP1 | c.2467G>T p.E823* | Nonsense Mutation (SNP) | VAF 40/260 reads (15%) | catalogued as COSV57044618; called by muse, mutect2, varscan2
- TACR3 | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 46/327 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs1208727441, COSV59209228; called by muse, mutect2, varscan2
- TAF1L | c.2997G>T p.E999D | Missense Mutation (SNP) | VAF 260/1066 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.449); catalogued as COSV54257099; called by muse, mutect2, varscan2
- TANC1 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 37/243 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs1460073010, COSV55091360; called by muse, mutect2, varscan2
- TBX15 | c.999C>G p.D333E (on ENST00000369429 / NM_001330677.2; = p.D227E on NM_152380.3) | Missense Mutation (SNP) | VAF 166/1058 reads (16%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.792); catalogued as COSV99254346; called by muse, mutect2, varscan2
- TCN2 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 51/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99308436; called by muse, varscan2
- TENM1 | c.6565G>T p.A2189S | Missense Mutation (SNP) | VAF 135/245 reads (55%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.971); catalogued as rs1393561209; called by muse, mutect2, varscan2
- TGFBR1 | c.99G>T p.A33= | Splice Region (SNP) | VAF 126/432 reads (29%) | catalogued as rs779055286, COSV66625361; called by muse, mutect2, varscan2
- THAP6 | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 84/695 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.778); catalogued as COSV61009434; called by muse, mutect2, varscan2
- THEMIS | c.1852G>T p.E618* | Nonsense Mutation (SNP) | VAF 80/224 reads (36%) | catalogued as COSV64072264; called by muse, mutect2, varscan2
- THSD7A | c.511G>T p.D171Y | Missense Mutation (SNP) | VAF 113/301 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1364767446; called by muse, mutect2, varscan2
- TMEFF2 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99772136; called by muse, mutect2, varscan2
- TMEM131 | c.4699G>A p.V1567I | Missense Mutation (SNP) | VAF 54/219 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.979); catalogued as rs775517653, COSV51777452; called by muse, mutect2, varscan2
- TMEM14A | c.122A>G p.Y41C | Missense Mutation (SNP) | VAF 48/375 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs751424236; called by muse, mutect2, varscan2
- TMEM45A | c.631G>C p.D211H | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV60256155; called by muse, mutect2, varscan2
- TMPRSS7 | c.701G>A p.R234Q | Missense Mutation (SNP) | VAF 54/346 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs1000824254; called by muse, mutect2, varscan2
- TNFRSF8 | c.1513G>T p.V505L | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs1373050058; called by muse, mutect2, varscan2
- TNS3 | c.3484G>A p.V1162M | Missense Mutation (SNP) | VAF 63/608 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1414215097, COSV60795819; called by muse, mutect2
- TRAF1 | c.706G>T p.V236L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as COSV100875168, COSV65867932; called by muse, varscan2
- TRHDE | c.2307C>A p.D769E | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV53871273; called by muse, mutect2, varscan2
- TRIM42 | c.1432G>T p.D478Y | Missense Mutation (SNP) | VAF 123/503 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99648347; called by muse, mutect2, varscan2
- TRIM48 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 40/325 reads (12%) | catalogued as rs772031761, COSV70161424; called by muse, mutect2, varscan2
- TRIM64B | c.1202G>T p.R401M | Missense Mutation (SNP) | VAF 136/1380 reads (10%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.934); catalogued as COSV61693604; called by muse, mutect2
- TSGA13 | c.774C>A p.F258L | Missense Mutation (SNP) | VAF 356/687 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs1563076899, COSV58405204; called by muse, mutect2, varscan2
- TTN | c.15265G>T p.A5089S (on ENST00000591111; = p.A4162S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/422 reads (10%) | PolyPhen benign (0.005); catalogued as COSV100630094; called by muse, mutect2, varscan2
- UBC | c.1911G>C p.K637N | Missense Mutation (SNP) | VAF 130/1000 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as COSV60060677; called by muse, varscan2
- UGT3A1 | c.1480G>T p.G494W | Missense Mutation (SNP) | VAF 139/502 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); catalogued as rs755225814, COSV99955101; called by muse, mutect2, varscan2
- USH2A | c.6779C>T p.S2260F | Missense Mutation (SNP) | VAF 100/648 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CM1514193; called by muse, mutect2, varscan2
- USP28 | c.2908C>T p.H970Y | Missense Mutation (SNP) | VAF 39/224 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as COSV99134603; called by muse, mutect2, varscan2
- USP34 | c.1792G>T p.A598S | Missense Mutation (SNP) | VAF 150/638 reads (24%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.976); catalogued as rs370929108; called by muse, mutect2, varscan2
- VANGL2 | c.530G>T p.R177L | Missense Mutation (SNP) | VAF 136/773 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as CM114448, COSV63604698; called by muse, mutect2, varscan2
- VWF | c.4514G>T p.G1505V | Missense Mutation (SNP) | VAF 394/927 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM910405; called by muse, mutect2, varscan2
- WLS | c.1387G>C p.G463R | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1402456775, COSV52042085; called by muse, mutect2, varscan2
- WT1 | c.703C>G p.H235D | Missense Mutation (SNP) | VAF 95/626 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60082539; called by muse, mutect2, varscan2
- XKR3 | c.360C>A p.Y120* | Nonsense Mutation (SNP) | VAF 45/253 reads (18%) | catalogued as COSV58884907; called by muse, varscan2
- XPO1 | c.1385-4G>C | Splice Region (SNP) | VAF 31/207 reads (15%) | catalogued as rs758813822; called by muse, mutect2, varscan2
- Z83844.2 | c.1673G>A p.R558H | Missense Mutation (SNP) | VAF 84/528 reads (16%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.941); catalogued as rs758065277, COSV53216570; called by muse, mutect2, varscan2
- ZFAT | c.1316A>T p.H439L | Missense Mutation (SNP) | VAF 73/461 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV64747640; called by muse, mutect2, varscan2
- ZFP42 | c.826G>T p.V276L | Missense Mutation (SNP) | VAF 164/429 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs201868683, COSV58816381; called by muse, mutect2, varscan2
- ZKSCAN7 | c.940G>A p.V314I | Missense Mutation (SNP) | VAF 25/118 reads (21%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs146954712; called by muse, mutect2, varscan2
- ZNF512B | c.1918C>T p.R640* | Nonsense Mutation (SNP) | VAF 17/157 reads (11%) | catalogued as COSV53868887; called by muse, mutect2, varscan2
- ZNF658 | c.556G>T p.E186* | Nonsense Mutation (SNP) | VAF 46/158 reads (29%) | catalogued as rs772640416; called by muse, mutect2, varscan2
- ZNF679 | c.641G>T p.C214F | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV55376451; called by muse, mutect2, varscan2
- ZNF99 | c.1769A>T p.E590V | Missense Mutation (SNP) | VAF 109/429 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs752556885, COSV68054895; called by muse, mutect2, varscan2
- ZZZ3 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 25/141 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as COSV100890297; called by muse, mutect2, varscan2
- ABCA13 | c.2730G>T p.Q910H | Missense Mutation (SNP) | VAF 102/941 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ABCA2 | c.3823C>T p.P1275S (on ENST00000614293; = p.P1245S on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- ABCA8 | c.1711G>T p.D571Y | Missense Mutation (SNP) | VAF 95/387 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ABCG4 | c.751C>A p.R251S | Missense Mutation (SNP) | VAF 57/340 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); called by muse, mutect2, varscan2
- ABLIM1 | c.1793G>T p.R598I | Missense Mutation (SNP) | VAF 77/638 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ACOT12 | c.1230T>A p.F410L | Missense Mutation (SNP) | VAF 71/201 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ACSL4 | c.2069A>T p.K690I (on ENST00000340800 / NM_022977.2; = p.K649I on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 110/226 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM5 | c.595G>T p.G199C | Missense Mutation (SNP) | VAF 104/547 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACSM5 | c.1413C>A p.N471K | Missense Mutation (SNP) | VAF 67/364 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- ACTRT1 | c.367G>C p.A123P | Missense Mutation (SNP) | VAF 81/158 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- ACVR1B | c.941G>T p.G314V | Missense Mutation (SNP) | VAF 190/435 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACVR2B | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 147/840 reads (18%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- ADAM20 | c.1508G>T p.C503F | Missense Mutation (SNP) | VAF 101/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM32 | c.1963A>G p.I655V | Missense Mutation (SNP) | VAF 47/304 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTS12 | c.3642C>A p.S1214R | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- ADAMTS5 | c.2432G>T p.W811L | Missense Mutation (SNP) | VAF 31/156 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAMTS9 | c.5747del p.G1916Vfs*22 | Frame Shift Del (DEL) | VAF 38/342 reads (11%) | called by mutect2, pindel, varscan2
- ADAR | c.2297dup p.R767Sfs*76 | Frame Shift Ins (INS) | VAF 77/539 reads (14%) | called by mutect2, pindel, varscan2
- ADGRB2 | c.2020G>T p.D674Y | Missense Mutation (SNP) | VAF 88/436 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- AFF1 | c.3152+1G>C p.X1051_splice | Splice Site (SNP) | VAF 29/132 reads (22%) | called by muse, mutect2, varscan2
- AFF2 | c.2978C>T p.T993I | Missense Mutation (SNP) | VAF 237/393 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFF4 | c.2187G>C p.K729N | Missense Mutation (SNP) | VAF 59/422 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.239); called by muse, mutect2, varscan2
- AFM | c.292del p.I98Yfs*62 | Frame Shift Del (DEL) | VAF 125/451 reads (28%) | called by mutect2, pindel, varscan2
- AGO2 | c.632G>T p.W211L | Missense Mutation (SNP) | VAF 38/305 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.904); called by muse, mutect2, varscan2
- AL121899.2 | c.322del p.Q108Rfs*8 | Frame Shift Del (DEL) | VAF 52/330 reads (16%) | called by mutect2, pindel, varscan2
- AL645922.1 | c.3646G>A p.V1216I | Missense Mutation (SNP) | VAF 120/687 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ALPK2 | c.3563G>T p.G1188V | Missense Mutation (SNP) | VAF 37/161 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ANKRD11 | c.1508A>C p.K503T | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ANKS1B | c.2084G>T p.G695V | Missense Mutation (SNP) | VAF 193/405 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- ANXA8L1 | c.618C>G p.C206W | Missense Mutation (SNP) | VAF 139/575 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- AP1S1 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 78/649 reads (12%) | called by muse, mutect2, varscan2
- AP2S1 | c.96C>G p.I32M | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- AP3B2 | c.2845T>A p.C949S (on ENST00000261722; = p.C943S on NM_004644.5) | Missense Mutation (SNP) | VAF 32/343 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.144); called by muse, mutect2, varscan2
- AQP10 | c.290G>T p.W97L | Missense Mutation (SNP) | VAF 103/554 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARFGEF1 | c.4163A>T p.E1388V | Missense Mutation (SNP) | VAF 128/324 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, varscan2
- ARHGEF33 | c.1090G>T p.D364Y | Missense Mutation (SNP) | VAF 119/451 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ARID2 | c.853dup p.R285Pfs*15 | Frame Shift Ins (INS) | VAF 131/393 reads (33%) | called by mutect2, pindel, varscan2
- ARL13B | c.381-1G>T p.X127_splice (on ENST00000394222 / NM_001174150.2; = p.X20_splice on NM_144996.4) | Splice Site (SNP) | VAF 91/453 reads (20%) | called by muse, mutect2, varscan2
- ARPP21 | c.662_664del p.I221del | In Frame Del (DEL) | VAF 36/228 reads (16%) | called by pindel, varscan2
- ARSF | c.162-1G>T p.X54_splice | Splice Site (SNP) | VAF 34/161 reads (21%) | called by muse, mutect2, varscan2
- ARSF | c.162G>T p.R54S | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- ASCC3 | c.4147G>T p.A1383S | Missense Mutation (SNP) | VAF 99/310 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ASPM | c.9032G>T p.W3011L | Missense Mutation (SNP) | VAF 45/323 reads (14%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ASTE1 | c.958G>T p.A320S | Missense Mutation (SNP) | VAF 145/640 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ASXL3 | c.4189T>A p.C1397S | Missense Mutation (SNP) | VAF 43/241 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATP13A3 | c.2183A>G p.Q728R | Missense Mutation (SNP) | VAF 114/496 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP4A | c.736A>T p.S246C | Missense Mutation (SNP) | VAF 71/219 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- AXDND1 | c.821G>T p.S274I | Missense Mutation (SNP) | VAF 117/733 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- B2M | c.141_142del p.S48Wfs*8 | Frame Shift Del (DEL) | VAF 109/618 reads (18%) | called by pindel, varscan2
- BAG6 | c.1630G>T p.V544L (on ENST00000676571; = p.V497L on NM_080702.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BBS5 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 48/330 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- BCAT1 | c.545T>G p.L182R | Missense Mutation (SNP) | VAF 42/304 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- BDH2 | c.357+1G>T p.X119_splice | Splice Site (SNP) | VAF 66/210 reads (31%) | called by muse, varscan2
- BMP7 | c.583T>C p.Y195H | Missense Mutation (SNP) | VAF 87/722 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- C11orf87 | c.554C>A p.T185K | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- C18orf63 | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 35/207 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- C7 | c.1337delinsGG p.E446Gfs*6 | Frame Shift Ins (INS) | VAF 41/476 reads (9%) | called by mutect2*, pindel
- C9orf135 | c.40dup p.R14Kfs*41 | Frame Shift Ins (INS) | VAF 80/268 reads (30%) | called by mutect2, pindel, varscan2
- C9orf43 | c.1141G>C p.D381H | Missense Mutation (SNP) | VAF 177/392 reads (45%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- CA9 | c.124del p.R42Gfs*67 | Frame Shift Del (DEL) | VAF 88/306 reads (29%) | called by mutect2, pindel, varscan2
- CACNA1G | c.5182G>T p.G1728C | Missense Mutation (SNP) | VAF 36/207 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D1 | c.2999C>A p.S1000Y (on ENST00000356253 / NM_001366867.1; = p.S988Y on NM_000722.4) | Missense Mutation (SNP) | VAF 56/530 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- CACNA2D4 | c.2448C>A p.N816K | Missense Mutation (SNP) | VAF 34/230 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- CAD | c.5401G>C p.V1801L | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2
- CALB2 | c.389A>T p.N130I | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- CALR3 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 258/770 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.069); called by muse, varscan2
- CAMK1D | c.1013G>T p.S338I | Missense Mutation (SNP) | VAF 108/476 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CAPZA3 | c.255C>A p.D85E | Missense Mutation (SNP) | VAF 192/493 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- CARMIL3 | c.2623C>A p.Q875K | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CASP5 | c.213G>T p.M71I | Missense Mutation (SNP) | VAF 38/179 reads (21%) | SIFT tolerated (0.67); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CCDC50 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 42/456 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.059); called by muse, mutect2
- CCDC88A | c.5039T>C p.V1680A (on ENST00000436346 / NM_001365480.1; = p.V1652A on NM_018084.5) | Missense Mutation (SNP) | VAF 95/623 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CCM2 | c.914C>T p.T305M | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CCNE1 | c.953G>T p.G318V | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CDC27 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, varscan2
- CDH22 | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 30/85 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- CDH7 | c.1818T>A p.S606R | Missense Mutation (SNP) | VAF 81/450 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- CDK5RAP3 | c.303A>G p.I101M | Missense Mutation (SNP) | VAF 96/289 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- CEACAM21 | c.716T>C p.L239P (on ENST00000401445 / NM_001098506.4; = p.L238P on NM_033543.6) | Missense Mutation (SNP) | VAF 124/356 reads (35%) | SIFT tolerated (0.17); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- CERS1 | c.210G>T p.W70C | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CFAP94 | c.809C>T p.S270L (on ENST00000320267 / NM_001352064.2; = p.S276L on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 345/711 reads (49%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHAT | c.1207A>T p.R403W | Missense Mutation (SNP) | VAF 118/301 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CHRNA4 | c.1528C>A p.L510M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- CILP | c.210C>G p.D70E | Missense Mutation (SNP) | VAF 42/265 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CLCA1 | c.1183-1G>T p.X395_splice | Splice Site (SNP) | VAF 41/190 reads (22%) | called by muse, mutect2, varscan2
- CLECL1 | c.95G>T p.W32L | Missense Mutation (SNP) | VAF 122/302 reads (40%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); called by muse, mutect2, varscan2
- CNKSR1 | c.1858G>T p.V620L (on ENST00000374253 / NM_001297647.2; = p.V613L on NM_006314.3) | Missense Mutation (SNP) | VAF 39/250 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- CNTN1 | c.839A>T p.E280V | Missense Mutation (SNP) | VAF 149/405 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- CNTNAP4 | c.2344C>A p.P782T | Missense Mutation (SNP) | VAF 105/243 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- COL11A1 | c.2713A>T p.T905S | Missense Mutation (SNP) | VAF 127/739 reads (17%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- COL22A1 | c.4535G>T p.G1512V | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL25A1 | c.975+2T>C p.X325_splice | Splice Site (SNP) | VAF 28/173 reads (16%) | called by muse, mutect2, varscan2
- COL6A3 | c.7472T>A p.M2491K | Missense Mutation (SNP) | VAF 164/681 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL6A3 | c.5533G>T p.G1845C | Missense Mutation (SNP) | VAF 61/392 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- COL6A6 | c.4051G>A p.G1351R | Missense Mutation (SNP) | VAF 84/371 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRACD | c.1472T>A p.L491H | Missense Mutation (SNP) | VAF 82/335 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.693); called by muse, mutect2, varscan2
- CRACR2A | c.2031del p.T678Rfs*5 | Frame Shift Del (DEL) | VAF 35/265 reads (13%) | called by mutect2, pindel
- CRH | c.97G>A p.G33R | Missense Mutation (SNP) | VAF 35/231 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CRISPLD1 | c.1127G>A p.G376D | Missense Mutation (SNP) | VAF 26/214 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); called by muse, varscan2
- CRPPA | c.1117dup p.S373Ffs*6 (on ENST00000407010 / NM_001368197.1; = p.S323Ffs*6 on NM_001101417.4) | Frame Shift Ins (INS) | VAF 26/196 reads (13%) | called by mutect2, pindel, varscan2
- CRTAM | c.396T>A p.N132K | Missense Mutation (SNP) | VAF 66/344 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- CRYZ | c.832G>T p.E278* | Nonsense Mutation (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- CSAG1 | c.164A>G p.K55R | Missense Mutation (SNP) | VAF 190/567 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- CSAG3 | c.310T>A p.S104T | Missense Mutation (SNP) | VAF 42/301 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.682); called by mutect2, varscan2
- CSRP2 | c.386C>G p.A129G | Missense Mutation (SNP) | VAF 158/356 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.904); called by muse, varscan2
- CTCFL | c.1382G>T p.R461L | Missense Mutation (SNP) | VAF 65/545 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- CTNND2 | c.257G>T p.G86V | Missense Mutation (SNP) | VAF 122/406 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- CUL1 | c.1141G>T p.V381L | Missense Mutation (SNP) | VAF 58/772 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- CXCR4 | c.97A>C p.N33H | Missense Mutation (SNP) | VAF 108/999 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- CYP27A1 | c.287G>C p.W96S | Missense Mutation (SNP) | VAF 79/583 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- CYP3A5 | c.799-3T>C | Splice Region (SNP) | VAF 42/436 reads (10%) | called by muse, mutect2
- DBH | c.956T>A p.F319Y | Missense Mutation (SNP) | VAF 330/705 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- DCAF12L1 | c.1123del p.Y375Mfs*44 | Frame Shift Del (DEL) | VAF 44/130 reads (34%) | called by mutect2, pindel*, varscan2
- DCC | c.535G>T p.D179Y | Missense Mutation (SNP) | VAF 130/727 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- DDX31 | c.1273C>A p.L425I | Missense Mutation (SNP) | VAF 77/431 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DDX46 | c.1941G>A p.M647I | Missense Mutation (SNP) | VAF 109/340 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- DEFB115 | c.5T>C p.L2P | Missense Mutation (SNP) | VAF 65/322 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- DENND4A | c.2284A>G p.R762G | Missense Mutation (SNP) | VAF 110/972 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.476); called by muse, mutect2
- DEPDC1 | c.220C>T p.Q74* | Nonsense Mutation (SNP) | VAF 79/534 reads (15%) | called by muse, mutect2, varscan2
- DEPDC5 | c.3598G>T p.A1200S (on ENST00000400246; = p.A1269S on NM_014662.5) | Missense Mutation (SNP) | VAF 95/574 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.627); called by muse, mutect2, varscan2
- DERPC | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DES | c.770A>T p.Q257L | Missense Mutation (SNP) | VAF 88/573 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- DGKI | c.761T>A p.V254E | Missense Mutation (SNP) | VAF 153/414 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DLG2 | c.1511-2A>T p.X504_splice | Splice Site (SNP) | VAF 51/315 reads (16%) | called by muse, mutect2, varscan2
- DMAP1 | c.910G>T p.V304F | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.713); called by muse, varscan2
- DMXL1 | c.6187C>T p.L2063F | Missense Mutation (SNP) | VAF 39/271 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAAF1 | c.1210A>T p.K404* | Nonsense Mutation (SNP) | VAF 359/751 reads (48%) | called by muse, mutect2, varscan2
- DNAH1 | c.4457G>T p.R1486L | Missense Mutation (SNP) | VAF 76/327 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- DNAH12 | c.8563C>A p.Q2855K (on ENST00000351747; = p.Q3723K on NM_001366028.2) | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DNAH17 | c.10339C>G p.Q3447E | Missense Mutation (SNP) | VAF 72/480 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH9 | c.12110C>T p.T4037I | Missense Mutation (SNP) | VAF 42/128 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.85); called by muse, varscan2
- DNAJA3 | c.1242-2A>T p.X414_splice | Splice Site (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2, varscan2
- DNM1 | c.2262G>T p.M754I | Missense Mutation (SNP) | VAF 54/353 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DPP6 | c.2472_2482del p.H824Qfs*79 (on ENST00000377770 / NM_001364500.2; = p.H762Qfs*79 on NM_001936.5) | Frame Shift Del (DEL) | VAF 36/378 reads (10%) | called by mutect2, pindel, varscan2
- DPP9 | c.926-1G>T p.X309_splice (on ENST00000598800; = p.X338_splice on NM_139159.5) | Splice Site (SNP) | VAF 41/131 reads (31%) | called by muse, mutect2, varscan2
- DSCAML1 | c.5087G>T p.S1696I (on ENST00000321322; = p.S1636I on NM_020693.4) | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG1 | c.502G>C p.E168Q | Missense Mutation (SNP) | VAF 116/691 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSPP | c.1850G>T p.S617I | Missense Mutation (SNP) | VAF 22/222 reads (10%) | SIFT tolerated, low confidence (0.47); PolyPhen possibly damaging (0.61); called by muse, mutect2
- DST | c.19217T>A p.L6406Q (on ENST00000361203 / NM_001374722.1; = p.L4103Q on NM_015548.5) | Missense Mutation (SNP) | VAF 54/337 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- DUS2 | c.344G>T p.G115V | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DYNC1H1 | c.8099G>T p.W2700L | Missense Mutation (SNP) | VAF 389/1066 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EGFLAM | c.2288T>C p.I763T | Missense Mutation (SNP) | VAF 12/136 reads (9%) | SIFT tolerated (0.31); PolyPhen benign (0.006); called by muse, mutect2
- EIF4G3 | c.1863G>T p.K621N | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- ELFN2 | c.1585G>T p.G529C | Missense Mutation (SNP) | VAF 44/184 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- EPHB1 | c.1289A>G p.N430S | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.248); called by muse, mutect2
- ERC2 | c.566A>T p.E189V | Missense Mutation (SNP) | VAF 90/650 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ERVFRD-1 | c.67C>T p.P23S | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- EVI2B | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- EVI5 | c.1292G>T p.R431M | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EYA1 | c.1256G>T p.C419F | Missense Mutation (SNP) | VAF 144/635 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- EYS | c.4313T>A p.L1438Q | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- EYS | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- F13A1 | c.116G>C p.G39A | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- F13B | c.1544G>T p.C515F | Missense Mutation (SNP) | VAF 39/243 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- F5 | c.2117C>T p.T706I | Missense Mutation (SNP) | VAF 130/824 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- FAM171B | c.506A>G p.Q169R | Missense Mutation (SNP) | VAF 54/228 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.177); called by muse, varscan2
- FAM184A | c.172T>G p.L58V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by mutect2, varscan2
- FAM187B | c.680C>A p.T227K | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FAM20A | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT tolerated (0.8); PolyPhen benign (0); called by muse, mutect2, varscan2
- FAM47A | c.2231T>C p.L744P | Missense Mutation (SNP) | VAF 30/119 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- FAM53B | c.427A>C p.K143Q | Missense Mutation (SNP) | VAF 49/162 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM53C | c.425G>T p.W142L | Missense Mutation (SNP) | VAF 114/302 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM91A1 | c.1333C>G p.L445V | Missense Mutation (SNP) | VAF 93/764 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FANCM | c.5560G>C p.D1854H | Missense Mutation (SNP) | VAF 160/473 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FAT3 | c.3142G>C p.V1048L | Missense Mutation (SNP) | VAF 55/351 reads (16%) | SIFT tolerated (0.66); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FAT3 | c.5081C>A p.S1694Y | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, varscan2
- FAT3 | c.13022C>A p.S4341Y | Missense Mutation (SNP) | VAF 64/443 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FAT4 | c.2118C>A p.S706R | Missense Mutation (SNP) | VAF 70/468 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- FAT4 | c.3342G>T p.R1114S | Missense Mutation (SNP) | VAF 37/362 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FAT4 | c.10708A>C p.T3570P | Missense Mutation (SNP) | VAF 93/431 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FCN2 | c.176C>G p.P59R | Missense Mutation (SNP) | VAF 140/355 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- FCN3 | c.471A>T p.Q157H | Missense Mutation (SNP) | VAF 28/213 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FHAD1 | c.1557+7C>A | Splice Region (SNP) | VAF 29/105 reads (28%) | called by muse, mutect2, varscan2
- FLT3LG | c.684G>T p.Q228H | Missense Mutation (SNP) | VAF 72/199 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FMN2 | c.3946del p.E1316Kfs*8 | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- FN1 | c.845-1G>C p.X282_splice | Splice Site (SNP) | VAF 92/828 reads (11%) | called by muse, mutect2, varscan2
- FNDC1 | c.4441C>G p.R1481G | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.756); called by muse, varscan2
- FOLH1 | c.1054G>T p.V352L | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FOXD3 | c.1198G>T p.V400F | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.003); called by muse, varscan2
- FRAS1 | c.4891T>A p.F1631I | Missense Mutation (SNP) | VAF 99/693 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FST | c.964G>T p.D322Y | Missense Mutation (SNP) | VAF 101/366 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- FTCD | c.191A>T p.N64I | Missense Mutation (SNP) | VAF 34/216 reads (16%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- FZD5 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 95/360 reads (26%) | SIFT tolerated (0.17); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- GABRG2 | c.485G>C p.W162S | Missense Mutation (SNP) | VAF 145/477 reads (30%) | SIFT tolerated (0.81); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GALNT6 | c.278del p.F93Sfs*7 | Frame Shift Del (DEL) | VAF 122/322 reads (38%) | called by mutect2, pindel, varscan2
- GATA3 | c.388C>A p.L130I | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.202); called by muse, mutect2
- GBA3 | c.1402C>A p.H468N | Missense Mutation (SNP) | VAF 168/404 reads (42%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GCAT | c.784A>C p.T262P | Missense Mutation (SNP) | VAF 26/149 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- GDA | c.1297G>T p.D433Y | Missense Mutation (SNP) | VAF 192/474 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GGPS1 | c.354G>T p.Q118H | Missense Mutation (SNP) | VAF 39/186 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); called by muse, mutect2, varscan2
- GIMAP1 | c.776G>T p.W259L | Missense Mutation (SNP) | VAF 33/277 reads (12%) | SIFT tolerated (0.65); PolyPhen benign (0.143); called by muse, mutect2, varscan2
- GLUD1 | c.949A>T p.M317L | Missense Mutation (SNP) | VAF 140/1007 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- GPR162 | c.1110T>A p.D370E (on ENST00000311268 / NM_019858.2; = p.D86E on NM_014449.2) | Missense Mutation (SNP) | VAF 48/298 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- GPR55 | c.497A>G p.Y166C | Missense Mutation (SNP) | VAF 121/424 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- GPR61 | c.800C>A p.T267N | Missense Mutation (SNP) | VAF 24/226 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- GRAMD1B | c.1491-2A>T p.X497_splice | Splice Site (SNP) | VAF 82/571 reads (14%) | called by muse, mutect2, varscan2
- GRIK4 | c.1267A>G p.I423V | Missense Mutation (SNP) | VAF 53/237 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- GRIK4 | c.2124G>T p.E708D | Missense Mutation (SNP) | VAF 71/562 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRK2 | c.443del p.P148Hfs*39 | Frame Shift Del (DEL) | VAF 35/240 reads (15%) | called by mutect2, pindel, varscan2
- GTF3C2 | c.1899del p.S634Vfs*17 | Frame Shift Del (DEL) | VAF 41/309 reads (13%) | called by mutect2, pindel, varscan2
- GTF3C3 | c.799C>G p.H267D | Missense Mutation (SNP) | VAF 55/420 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- GUCY1B1 | c.44G>T p.R15L | Missense Mutation (SNP) | VAF 85/282 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- H1-3 | c.203C>G p.A68G | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HABP2 | c.299dup p.A101Gfs*7 | Frame Shift Ins (INS) | VAF 104/380 reads (27%) | called by mutect2, pindel, varscan2
- HAPLN1 | c.325C>A p.Q109K | Missense Mutation (SNP) | VAF 115/344 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- HCN3 | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 78/380 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, varscan2
- HELLS | c.2374A>T p.I792F | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.069); called by muse, mutect2
- HELZ2 | c.304G>T p.A102S | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.93); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- HEPH | c.2192C>A p.A731D (on ENST00000343002; = p.A464D on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 77/245 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- HERC1 | c.6170G>T p.G2057V | Missense Mutation (SNP) | VAF 41/220 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HIGD2B | c.167C>A p.T56K | Missense Mutation (SNP) | VAF 89/561 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HMCN1 | c.1844C>A p.T615N | Missense Mutation (SNP) | VAF 51/427 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- HNRNPCL2 | c.233A>T p.Q78L | Missense Mutation (SNP) | VAF 81/441 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.17); called by muse, mutect2, varscan2
- HNRNPM | c.1833G>T p.M611I | Missense Mutation (SNP) | VAF 45/188 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- HOXB4 | c.704G>T p.G235V | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.278); called by muse, varscan2
- HOXD11 | c.578C>A p.P193Q | Missense Mutation (SNP) | VAF 40/157 reads (25%) | SIFT tolerated (0.34); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- HOXD8 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 61/266 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, varscan2
- HOXD9 | c.301C>G p.P101A | Missense Mutation (SNP) | VAF 15/109 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HRNR | c.661C>A p.H221N | Missense Mutation (SNP) | VAF 89/511 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- HS3ST4 | c.1220G>T p.R407M | Missense Mutation (SNP) | VAF 149/849 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HSPA13 | c.785G>T p.R262I | Missense Mutation (SNP) | VAF 45/210 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- HTT | c.6194C>T p.S2065F | Missense Mutation (SNP) | VAF 53/345 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HUWE1 | c.9650A>G p.Q3217R | Missense Mutation (SNP) | VAF 108/193 reads (56%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- HYOU1 | c.830T>A p.L277H | Missense Mutation (SNP) | VAF 38/195 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IFNA21 | c.68G>T p.G23V | Missense Mutation (SNP) | VAF 102/350 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.563); called by muse, varscan2
- IGDCC3 | c.794C>A p.P265Q | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGF2BP1 | c.532C>A p.R178S | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- IGHV3-48 | c.34G>T p.A12S | Missense Mutation (SNP) | VAF 137/435 reads (31%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- IGHV3-73 | c.263G>T p.R88M | Missense Mutation (SNP) | VAF 124/374 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- IGSF6 | c.31C>G p.R11G | Missense Mutation (SNP) | VAF 76/394 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- IL22RA1 | c.955C>T p.H319Y | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- IL7R | c.1156A>T p.R386W | Missense Mutation (SNP) | VAF 90/262 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- INHBA | c.1024C>A p.P342T | Missense Mutation (SNP) | VAF 200/494 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- INSL6 | c.85G>T p.A29S | Missense Mutation (SNP) | VAF 179/464 reads (39%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- IQGAP2 | c.2283G>T p.L761F | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT tolerated (0.83); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ITPR2 | c.4844A>T p.H1615L | Missense Mutation (SNP) | VAF 143/288 reads (50%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- KCNA4 | c.1723G>T p.E575* | Nonsense Mutation (SNP) | VAF 38/220 reads (17%) | called by muse, mutect2, varscan2
- KCNA4 | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 28/195 reads (14%) | SIFT tolerated, low confidence (0.19); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KCNJ1 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KCNMA1 | c.699T>A p.F233L | Missense Mutation (SNP) | VAF 82/678 reads (12%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCNMA1 | c.697T>A p.F233I | Missense Mutation (SNP) | VAF 80/669 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNQ4 | c.1066G>C p.D356H | Missense Mutation (SNP) | VAF 47/354 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KCTD5 | c.482T>C p.L161P | Missense Mutation (SNP) | VAF 108/329 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- KIAA1109 | c.2149G>T p.E717* | Nonsense Mutation (SNP) | VAF 75/615 reads (12%) | called by muse, varscan2
- KIAA1109 | c.14536G>T p.V4846L | Missense Mutation (SNP) | VAF 55/465 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KIAA1217 | c.1203G>T p.E401D | Missense Mutation (SNP) | VAF 84/629 reads (13%) | SIFT tolerated (0.1); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- KLHL4 | c.674T>A p.M225K | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- KLRG2 | c.155G>T p.G52V | Missense Mutation (SNP) | VAF 112/204 reads (55%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- KPRP | c.1634G>T p.C545F | Missense Mutation (SNP) | VAF 54/384 reads (14%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRT72 | c.426G>C p.K142N | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- KRTAP2-4 | c.143C>A p.P48H | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- KRTAP4-7 | c.83G>T p.S28I | Missense Mutation (SNP) | VAF 63/383 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- KRTAP6-3 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 25/94 reads (27%) | PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- L3MBTL3 | c.2096G>T p.G699V | Missense Mutation (SNP) | VAF 136/367 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- LAD1 | c.723G>C p.K241N | Missense Mutation (SNP) | VAF 38/295 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- LAMA2 | c.8572G>C p.E2858Q | Missense Mutation (SNP) | VAF 122/674 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- LAMA3 | c.1378G>T p.G460* | Nonsense Mutation (SNP) | VAF 219/879 reads (25%) | called by muse, mutect2, varscan2
- LBR | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 110/704 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- LCE1B | c.57G>C p.K19N | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LCE5A | c.157G>T p.G53C | Missense Mutation (SNP) | VAF 85/474 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LGALS9C | c.512C>A p.P171Q | Missense Mutation (SNP) | VAF 40/573 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.466); called by muse, mutect2
- LHX8 | c.785C>A p.T262K | Missense Mutation (SNP) | VAF 80/462 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LIPM | c.574G>T p.G192C | Missense Mutation (SNP) | VAF 77/281 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LPL | c.754A>T p.I252F | Missense Mutation (SNP) | VAF 170/509 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- LRATD1 | c.136G>T p.E46* | Nonsense Mutation (SNP) | VAF 30/358 reads (8%) | called by muse, mutect2
- LRRC7 | c.1872G>T p.L624F (on ENST00000651989 / NM_001370785.2; = p.L591F on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/470 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- LRRC7 | c.2365A>T p.I789L (on ENST00000651989 / NM_001370785.2; = p.I756L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRIQ3 | c.128dup p.M43Ifs*11 | Frame Shift Ins (INS) | VAF 23/192 reads (12%) | called by mutect2, pindel, varscan2
- LRRN1 | c.1883C>T p.T628I | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- LTN1 | c.2437G>C p.A813P | Missense Mutation (SNP) | VAF 62/403 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- LYPD1 | c.113C>A p.S38Y | Missense Mutation (SNP) | VAF 81/315 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- LZTS1 | c.1170G>T p.E390D | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAGEB18 | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 44/159 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MAP3K4 | c.3936G>T p.M1312I | Missense Mutation (SNP) | VAF 44/160 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MARCHF4 | c.616G>T p.E206* | Nonsense Mutation (SNP) | VAF 52/148 reads (35%) | called by muse, mutect2, varscan2
- MARCO | c.659del p.X220_splice | Splice Site (DEL) | VAF 34/127 reads (27%) | called by mutect2, pindel, varscan2
- MBD5 | c.3538G>C p.D1180H | Missense Mutation (SNP) | VAF 98/891 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- MC2R | c.166C>A p.Q56K | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MCOLN3 | c.1360C>A p.L454M | Missense Mutation (SNP) | VAF 56/319 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- MED17 | c.1814C>T p.P605L | Missense Mutation (SNP) | VAF 95/589 reads (16%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MELTF | c.205-2A>T p.X69_splice | Splice Site (SNP) | VAF 56/250 reads (22%) | called by muse, mutect2, varscan2
- MFAP3L | c.904G>C p.D302H | Missense Mutation (SNP) | VAF 50/420 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MFSD1 | c.1259dup p.L420Ffs*46 | Frame Shift Ins (INS) | VAF 77/376 reads (20%) | called by mutect2, pindel, varscan2
- MGAM2 | c.2297G>A p.G766E | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- MINDY4B | c.614C>A p.T205N | Missense Mutation (SNP) | VAF 134/618 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- MLST8 | c.269C>A p.S90Y | Missense Mutation (SNP) | VAF 29/236 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- MRC1 | c.1666G>T p.G556C | Missense Mutation (SNP) | VAF 139/636 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRGPRX4 | c.565G>C p.V189L | Missense Mutation (SNP) | VAF 86/526 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.346); called by muse, varscan2
- MRPL15 | c.196G>T p.G66C | Missense Mutation (SNP) | VAF 61/568 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MTDH | c.746-2A>T p.X249_splice | Splice Site (SNP) | VAF 32/241 reads (13%) | called by muse, mutect2
- MTMR4 | c.2721G>T p.W907C | Missense Mutation (SNP) | VAF 190/633 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- MTR | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 115/692 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC12 | c.308G>C p.G103A | Missense Mutation (SNP) | VAF 13/183 reads (7%) | called by muse, mutect2
- MUC16 | c.40620G>T p.K13540N | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2
- MUC16 | c.35297G>T p.G11766V | Missense Mutation (SNP) | VAF 158/441 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- MUC17 | c.10666T>G p.S3556A | Missense Mutation (SNP) | VAF 47/417 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- MUC19 | c.10G>A p.G4R | Missense Mutation (SNP) | VAF 126/346 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.392); called by muse, mutect2, varscan2
- MUC22 | c.1801A>T p.T601S | Missense Mutation (SNP) | VAF 49/138 reads (36%) | SIFT tolerated (0.8); called by muse, mutect2, varscan2
- MUC3A | c.9069G>T p.E3023D | Missense Mutation (SNP) | VAF 37/789 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.382); called by muse, mutect2
- MUSK | c.1302C>A p.C434* | Nonsense Mutation (SNP) | VAF 96/338 reads (28%) | called by muse, mutect2, varscan2
- MYO3A | c.127A>T p.N43Y | Missense Mutation (SNP) | VAF 48/339 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- MYO7B | c.3952G>T p.E1318* | Nonsense Mutation (SNP) | VAF 22/150 reads (15%) | called by muse, mutect2
- MYOCD | c.2100T>G p.F700L | Missense Mutation (SNP) | VAF 64/377 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MYSM1 | c.553C>G p.Q185E | Missense Mutation (SNP) | VAF 47/260 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MYT1L | c.1958C>G p.T653S | Missense Mutation (SNP) | VAF 160/724 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- NAA15 | c.421C>G p.L141V | Missense Mutation (SNP) | VAF 134/563 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAB2 | c.1064C>T p.T355I | Missense Mutation (SNP) | VAF 137/282 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2, varscan2
- NAV3 | c.211del p.Q71Kfs*21 | Frame Shift Del (DEL) | VAF 84/206 reads (41%) | called by mutect2, pindel, varscan2
- NBAS | c.4763C>T p.P1588L | Missense Mutation (SNP) | VAF 122/551 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCAN | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NIPBL | c.3221G>T p.R1074L | Missense Mutation (SNP) | VAF 149/556 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NISCH | c.2005G>C p.G669R | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.247); called by muse, mutect2, varscan2
- NKAIN3 | c.157G>T p.G53W | Missense Mutation (SNP) | VAF 32/251 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NLGN4X | c.925C>A p.L309M | Missense Mutation (SNP) | VAF 102/376 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- NME9 | c.950C>A p.A317E | Missense Mutation (SNP) | VAF 128/517 reads (25%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOBOX | c.1184C>A p.P395H | Missense Mutation (SNP) | VAF 167/422 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- NOL10 | c.91G>C p.A31P | Missense Mutation (SNP) | VAF 49/316 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- NOX4 | c.1103G>A p.G368E | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- NPC1L1 | c.1084C>A p.P362T | Missense Mutation (SNP) | VAF 88/260 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NPY | c.63C>G p.C21W | Missense Mutation (SNP) | VAF 46/508 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.792); called by muse, mutect2
- NR0B1 | c.875C>T p.A292V | Missense Mutation (SNP) | VAF 100/306 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.994); called by muse, varscan2
- NRAP | c.2033A>T p.Q678L (on ENST00000359988 / NM_001322945.2; = p.Q643L on NM_006175.4) | Missense Mutation (SNP) | VAF 83/258 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NRBP1 | c.526-1G>C p.X176_splice | Splice Site (SNP) | VAF 50/382 reads (13%) | called by muse, mutect2, varscan2
- NRCAM | c.3473C>A p.A1158E (on ENST00000379028 / NM_001371124.1; = p.A1037E on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 81/379 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- NRCAM | c.749C>A p.A250D (on ENST00000379028 / NM_001371124.1; = p.A244D on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 104/440 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- NRXN1 | c.2006A>T p.K669M | Missense Mutation (SNP) | VAF 54/460 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- NRXN1 | c.265C>A p.L89M | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NT5E | c.655G>T p.G219* | Nonsense Mutation (SNP) | VAF 186/491 reads (38%) | called by muse, mutect2, varscan2
- OBSCN | c.12995C>A p.A4332D | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G9 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 24/341 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- OR14K1 | c.662C>A p.S221Y | Missense Mutation (SNP) | VAF 98/684 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- OR2AJ1 | c.729C>A p.F243L | Missense Mutation (SNP) | VAF 46/325 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- OR2T4 | c.358G>T p.G120C | Missense Mutation (SNP) | VAF 53/319 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- OR4D1 | c.211C>T p.L71F | Missense Mutation (SNP) | VAF 94/263 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR4X2 | c.734C>A p.P245H | Missense Mutation (SNP) | VAF 55/296 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR51C1P | c.775T>A p.S259T | Missense Mutation (SNP) | VAF 31/158 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- OR51I2 | c.259C>A p.L87I | Missense Mutation (SNP) | VAF 41/199 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- OR52E6 | c.575C>A p.A192D | Missense Mutation (SNP) | VAF 37/235 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- OR56A5 | c.488C>A p.P163H | Missense Mutation (SNP) | VAF 50/348 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR5R1 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 69/385 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- OR6N1 | c.725C>A p.A242D | Missense Mutation (SNP) | VAF 44/231 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- OR7D2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 84/191 reads (44%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.158); called by muse, mutect2, varscan2
- OTOS | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.53); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- OTUD6A | c.524C>G p.A175G | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OTUD7B | c.1463C>T p.S488L | Missense Mutation (SNP) | VAF 101/480 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- OXER1 | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 40/308 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- PALD1 | c.730G>T p.E244* | Nonsense Mutation (SNP) | VAF 28/334 reads (8%) | called by muse, mutect2
- PAMR1 | c.697T>C p.Y233H | Missense Mutation (SNP) | VAF 66/322 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- PANK1 | c.1120G>T p.V374F (on ENST00000307534 / NM_148977.2; = p.V149F on NM_138316.4) | Missense Mutation (SNP) | VAF 99/342 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- PAX4 | c.74A>G p.D25G | Missense Mutation (SNP) | VAF 116/1839 reads (6%) | SIFT tolerated (0.24); PolyPhen benign (0.045); called by muse, mutect2
- PCDH15 | c.3031G>T p.D1011Y | Missense Mutation (SNP) | VAF 172/568 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDHB11 | c.2050G>T p.D684Y | Missense Mutation (SNP) | VAF 183/509 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- PCDHB11 | c.2051A>T p.D684V | Missense Mutation (SNP) | VAF 183/509 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.234); called by muse, mutect2, varscan2
- PCDHGA1 | c.1663C>A p.Q555K | Missense Mutation (SNP) | VAF 123/366 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- PCNT | c.3145G>T p.E1049* | Nonsense Mutation (SNP) | VAF 38/218 reads (17%) | called by muse, mutect2, varscan2
- PDE1A | c.640T>A p.Y214N | Missense Mutation (SNP) | VAF 39/177 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PDGFRL | c.299G>C p.R100T | Missense Mutation (SNP) | VAF 70/242 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- PDIA5 | c.123A>T p.K41N | Missense Mutation (SNP) | VAF 25/262 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PDZD8 | c.183T>A p.Y61* | Nonsense Mutation (SNP) | VAF 14/174 reads (8%) | called by muse, mutect2
- PEG3 | c.2806C>A p.R936S | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PGK2 | c.567G>C p.L189F | Missense Mutation (SNP) | VAF 74/392 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PHEX | c.539G>C p.W180S | Missense Mutation (SNP) | VAF 146/415 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHF21A | c.1375G>A p.E459K | Missense Mutation (SNP) | VAF 27/161 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.834); called by muse, varscan2
- PKHD1L1 | c.714C>G p.S238R | Missense Mutation (SNP) | VAF 28/157 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2, varscan2
- PLA2G2A | c.383A>T p.K128M | Missense Mutation (SNP) | VAF 95/603 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- PLA2G4C | c.78T>A p.H26Q | Missense Mutation (SNP) | VAF 89/270 reads (33%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PLEKHB2 | c.732G>T p.Q244H | Missense Mutation (SNP) | VAF 4/12 reads (33%) | PolyPhen benign (0.216); called by mutect2, varscan2
- PLVAP | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 59/272 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.357); called by muse, mutect2, varscan2
- PLXNA4 | c.1971C>G p.S657R | Missense Mutation (SNP) | VAF 38/392 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLXNB1 | c.6229-2A>T p.X2077_splice | Splice Site (SNP) | VAF 55/346 reads (16%) | called by muse, mutect2, varscan2
- PLXNB2 | c.4729del p.E1577Sfs*32 | Frame Shift Del (DEL) | VAF 14/80 reads (18%) | called by mutect2, pindel, varscan2
- PMPCB | c.1036C>G p.L346V | Missense Mutation (SNP) | VAF 90/1054 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.137); called by muse, mutect2
- PNLIP | c.967C>A p.Q323K | Missense Mutation (SNP) | VAF 32/370 reads (9%) | SIFT tolerated (0.82); PolyPhen benign (0.014); called by muse, mutect2
- PNMA8B | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- POTEG | c.329G>C p.R110T | Missense Mutation (SNP) | VAF 175/2388 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.034); called by muse, mutect2
- PPARD | c.713A>G p.Y238C | Missense Mutation (SNP) | VAF 65/334 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- PPEF2 | c.1369G>T p.A457S | Missense Mutation (SNP) | VAF 61/375 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.21); called by muse, mutect2, varscan2
- PPP1R16B | c.1528G>T p.G510C | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- PPP1R1C | c.57G>T p.Q19H | Missense Mutation (SNP) | VAF 88/569 reads (15%) | SIFT tolerated (0.51); PolyPhen probably damaging (0.996); called by muse, mutect2
- PPP2R2C | c.885C>A p.Y295* | Nonsense Mutation (SNP) | VAF 210/514 reads (41%) | called by muse, mutect2, varscan2
- PRB3 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.013); called by muse, varscan2
- PREX1 | c.892C>G p.L298V | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRKG1 | c.698+1G>C p.X233_splice | Splice Site (SNP) | VAF 33/298 reads (11%) | called by muse, mutect2, varscan2
- PRRT2 | c.733C>A p.R245S | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- PRSS35 | c.352G>T p.V118F | Missense Mutation (SNP) | VAF 307/939 reads (33%) | SIFT tolerated (0.1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PSMD1 | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- PTOV1 | c.936G>T p.L312= | Splice Region (SNP) | VAF 49/133 reads (37%) | called by muse, mutect2, varscan2
- PWP1 | c.70A>G p.K24E | Missense Mutation (SNP) | VAF 39/350 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- RAB4A | c.256G>C p.A86P | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- RANBP2 | c.3050C>T p.P1017L | Missense Mutation (SNP) | VAF 297/1183 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RAPGEF1 | c.398A>T p.E133V | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RAPGEF1 | c.397G>T p.E133* | Nonsense Mutation (SNP) | VAF 113/313 reads (36%) | called by muse, mutect2, varscan2
- RC3H1 | c.3083A>T p.E1028V | Missense Mutation (SNP) | VAF 48/221 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RETREG1 | c.247G>C p.A83P | Missense Mutation (SNP) | VAF 88/632 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- RHCG | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 32/156 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- RIOK3 | c.764G>T p.G255V | Missense Mutation (SNP) | VAF 45/191 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RNASE9 | c.446A>C p.E149A | Missense Mutation (SNP) | VAF 57/185 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RNASEH1 | c.282A>T p.K94N | Missense Mutation (SNP) | VAF 93/353 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RNF212 | c.546G>T p.M182I | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- RPN1 | c.769C>A p.L257I | Missense Mutation (SNP) | VAF 121/933 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR1 | c.3610G>T p.G1204C | Missense Mutation (SNP) | VAF 206/554 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RYR2 | c.11258C>A p.P3753Q | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- RYR2 | c.12157G>T p.E4053* | Nonsense Mutation (SNP) | VAF 92/722 reads (13%) | called by muse, mutect2, varscan2
- RYR2 | c.14348T>A p.V4783E | Missense Mutation (SNP) | VAF 53/386 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SAMD1 | c.610del p.A204Pfs*101 | Frame Shift Del (DEL) | VAF 10/18 reads (56%) | called by mutect2, varscan2
- SARAF | c.457_460dup p.G154Afs*8 | Frame Shift Ins (INS) | VAF 165/682 reads (24%) | called by mutect2, pindel, varscan2
- SCGB1D4 | c.124G>T p.V42L | Missense Mutation (SNP) | VAF 92/448 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SCML2 | c.452G>T p.G151V | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SCN2A | c.3322G>C p.A1108P | Missense Mutation (SNP) | VAF 161/544 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SDK1 | c.5415del p.S1806Afs*8 | Frame Shift Del (DEL) | VAF 12/63 reads (19%) | called by mutect2, pindel, varscan2
- SEC11A | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 12/92 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA3E | c.2171G>A p.R724K | Missense Mutation (SNP) | VAF 120/1380 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.012); called by muse, mutect2
- SFRP2 | c.407G>C p.W136S | Missense Mutation (SNP) | VAF 144/412 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SGPP2 | c.537C>G p.I179M | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SH3D19 | c.1901C>A p.S634Y | Missense Mutation (SNP) | VAF 73/476 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- SHANK1 | c.4949C>A p.P1650Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.39); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- SHANK2 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 85/537 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SHISA6 | c.1335C>A p.H445Q (on ENST00000409168 / NM_001173461.1; = p.H496Q on NM_207386.4) | Missense Mutation (SNP) | VAF 137/377 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- SIPA1L1 | c.4116G>T p.M1372I | Missense Mutation (SNP) | VAF 255/879 reads (29%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- SIRPD | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); called by muse, varscan2
- SKOR2 | c.230A>T p.Y77F | Missense Mutation (SNP) | VAF 76/377 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLA | c.12C>A p.S4R (on ENST00000338087 / NM_001045556.3; = p.S44R on NM_006748.4) | Missense Mutation (SNP) | VAF 34/245 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.063); called by muse, varscan2
- SLC16A1 | c.262G>A p.V88I | Missense Mutation (SNP) | VAF 110/623 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SLC18A3 | c.1377C>A p.N459K | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- SLC1A6 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- SLC25A41 | c.608T>A p.L203H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2
- SLC28A3 | c.668G>T p.R223I | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SLC2A9 | c.38G>C p.G13A | Missense Mutation (SNP) | VAF 196/569 reads (34%) | SIFT tolerated, low confidence (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC37A2 | c.1073C>A p.T358N | Missense Mutation (SNP) | VAF 62/389 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- SLC49A3 | c.587T>G p.L196R | Missense Mutation (SNP) | VAF 34/268 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- SLC9C2 | c.1351C>G p.H451D | Missense Mutation (SNP) | VAF 49/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- SLFN11 | c.1922G>C p.S641T | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- SLIT1 | c.2881T>C p.C961R | Missense Mutation (SNP) | VAF 54/189 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLMAP | c.1351G>T p.E451* (on ENST00000428312 / NM_001377924.1; = p.E513* on NM_007159.5) | Nonsense Mutation (SNP) | VAF 40/248 reads (16%) | called by muse, mutect2, varscan2
- SMC1B | c.3295C>A p.P1099T | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); called by muse, mutect2, varscan2
- SMR3A | c.322C>A p.Q108K | Missense Mutation (SNP) | VAF 70/578 reads (12%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SNRNP200 | c.989A>T p.Y330F | Missense Mutation (SNP) | VAF 248/880 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.023); called by muse, varscan2
- SNRNP48 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.681); called by muse, mutect2
- SORCS3 | c.1721T>A p.V574E | Missense Mutation (SNP) | VAF 44/395 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- SP4 | c.1499C>T p.S500F | Missense Mutation (SNP) | VAF 91/680 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- SPEF2 | c.3985A>T p.I1329L | Missense Mutation (SNP) | VAF 20/203 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPTLC3 | c.1456G>T p.V486L | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRBD1 | c.2704G>A p.D902N | Missense Mutation (SNP) | VAF 52/164 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.1); called by muse, varscan2
- SRC | c.769G>A p.G257S | Missense Mutation (SNP) | VAF 29/153 reads (19%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- STMND1 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 69/371 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- STX16 | c.511G>T p.E171* (on ENST00000371141 / NM_001001433.3; = p.E150* on NM_003763.6) | Nonsense Mutation (SNP) | VAF 63/349 reads (18%) | called by muse, mutect2, varscan2
- STYXL2 | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 62/448 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUN1 | c.811G>T p.G271C (on ENST00000405266 / NM_001367651.1; = p.G234C on NM_001130965.3 and 17 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/444 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUN5 | c.77+1G>A p.X26_splice | Splice Site (SNP) | VAF 42/151 reads (28%) | called by muse, mutect2, varscan2
- SVEP1 | c.7917C>A p.D2639E | Missense Mutation (SNP) | VAF 62/401 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.017); called by muse, varscan2
- SVEP1 | c.7840G>T p.G2614C | Missense Mutation (SNP) | VAF 182/458 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SYCP2 | c.4328G>T p.W1443L | Missense Mutation (SNP) | VAF 54/190 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- SYNE2 | c.17545G>T p.E5849* | Nonsense Mutation (SNP) | VAF 203/618 reads (33%) | called by muse, mutect2, varscan2
- TAF1L | c.5317G>C p.E1773Q | Missense Mutation (SNP) | VAF 249/978 reads (25%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- TAF1L | c.2479C>A p.Q827K | Missense Mutation (SNP) | VAF 268/1182 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TAGLN2 | c.255G>T p.M85I | Missense Mutation (SNP) | VAF 44/237 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TANC2 | c.1356G>T p.V452= | Splice Region (SNP) | VAF 126/380 reads (33%) | called by muse, varscan2
- TAOK2 | c.305G>T p.W102L | Missense Mutation (SNP) | VAF 75/395 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TBC1D22B | c.1150G>T p.V384F | Missense Mutation (SNP) | VAF 51/377 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- TBX18 | c.1599C>G p.N533K | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- TCF19 | c.805C>A p.R269S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- TECRL | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 37/344 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TEKT1 | c.326T>C p.L109S | Missense Mutation (SNP) | VAF 85/200 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- TESPA1 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 114/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- TESPA1 | c.201T>A p.D67E | Missense Mutation (SNP) | VAF 120/364 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.809); called by muse, mutect2
- TEX14 | c.1271_1274dup p.E426Tfs*29 (on ENST00000240361 / NM_001201457.2; = p.E420Tfs*29 on NM_031272.5) | Frame Shift Ins (INS) | VAF 62/543 reads (11%) | called by mutect2, pindel, varscan2
- TG | c.5006A>G p.H1669R | Missense Mutation (SNP) | VAF 145/1390 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7B | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 43/171 reads (25%) | called by muse, mutect2, varscan2
- TIAM1 | c.980A>T p.E327V | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- TINAG | c.540G>T p.W180C | Missense Mutation (SNP) | VAF 33/168 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TLN2 | c.4924G>T p.V1642L | Missense Mutation (SNP) | VAF 49/296 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- TMEM131L | c.3517T>C p.S1173P | Missense Mutation (SNP) | VAF 29/386 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2
- TMEM176B | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 106/1297 reads (8%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2
- TNN | c.3021C>A p.Y1007* | Nonsense Mutation (SNP) | VAF 36/254 reads (14%) | called by muse, mutect2, varscan2
- TNR | c.276T>G p.S92R | Missense Mutation (SNP) | VAF 40/312 reads (13%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TNRC18 | c.5666A>T p.Q1889L | Missense Mutation (SNP) | VAF 25/211 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- TOPAZ1 | c.665C>T p.S222F | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- TPBG | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 29/106 reads (27%) | SIFT tolerated (0.15); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- TPST1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 66/511 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRAPPC12 | c.1570G>T p.G524C | Missense Mutation (SNP) | VAF 73/521 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.435); called by muse, mutect2, varscan2
- TRBV4-1 | c.73C>A p.Q25K | Missense Mutation (SNP) | VAF 167/335 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TRPC4 | c.2113C>A p.Q705K (on ENST00000379705 / NM_016179.4; = p.Q710K on NM_003306.3) | Missense Mutation (SNP) | VAF 33/223 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- TRPM2 | c.1991A>T p.K664M | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by mutect2, varscan2
- TSHZ2 | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 42/143 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TSHZ2 | c.1618G>C p.A540P | Missense Mutation (SNP) | VAF 58/234 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TTN | c.69449C>A p.T23150N (on ENST00000591111; = p.T15726N on NM_003319.4) | Missense Mutation (SNP) | VAF 21/165 reads (13%) | PolyPhen benign (0.344); called by muse, mutect2, varscan2
- TTN | c.44090G>T p.G14697V (on ENST00000591111; = p.G7273V on NM_003319.4) | Missense Mutation (SNP) | VAF 29/113 reads (26%) | PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.41396A>T p.K13799I (on ENST00000591111; = p.K6375I on NM_003319.4) | Missense Mutation (SNP) | VAF 35/144 reads (24%) | PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
425 further variants in this file (42 protein-altering or splice-affecting, 211 silent, 172 other) are not listed here.
